Surgical pathology report (de-identified scan), TCGA case TCGA-66-2773, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2773-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right lower lobe, among others

Clinical diagnosis and question

Bronchial carcinoma right – squamous cell -. Suspected asbestos exposure.

REPORT ON FINDINGS**Macroscopy**

- 1.) Right lower lobe: after attempted inflation of lower lobe at the deformed base measuring 10.5 x 7.5 cm and up to 12 cm high, central bronchus resection plane located at the level of the bifurcation of B6. At the hilus are two grayish-black nodes, 2 and 1.3 cm in size. Parenchyma shows incomplete atelectasis or compression by a tumor that is soft to moderately firm, focally softened and these areas yellowish, otherwise predominantly pale brownish, in sections with small grayish-black patches, with the main mass in segment 8 and adjacent sections of S6 and S9, max. 8.5 cm in size, with a predominantly clear and somewhat arcuate demarcation, extending right up to the pleura at the junction S6/8. Opening or truncation of intermediate branches of B8 in the tumor. Narrowing of some subsegmental branches of B6 and B9. Pleura shows diffuse dark discoloration and extensive ragged grayish-yellow coating.
- 2.) Parietal pleura: flat preparation 8.5 x 3.2 cm and up to 0.7 cm thick with turbid and patchy brownish discoloration, in some areas with ragged grayish-yellow coating of surface.
- 3.) Lobar LN (station 12) upper lobe right: 1.8 cm lesioned node or node part.
- 4.) Lobar LN (station 12) middle lobe right: 2 cm lesioned node or node part.
- 5.) Hilar LN (station 10) right: two 0.6 cm lesioned nodes or node parts.
- 6.) Pulmonary ligament LN (station 9) right: three lesioned grayish-black nodes or node parts between 0.3 and 0.4 cm, with some surrounding tissue in parts.
- 7.) Paraesophageal LN (station 8) right: 1.2 cm lesioned grayish-black node.
- 8.) Low paratracheal LN (station 4) right: four lesioned grayish-black nodes or node parts between 0.5 and 1.2 cm.
- 9.) Prevascular and retrotracheal LN (station 3) right: 2.2 cm lesioned node or node part.

Examined:

- 1.) 2 sections of tumor with rest of parenchyma, 3 sections with pleura, S8 ventrobasal, S10 dorsal, central bronchus resection plane, resection margins of vessels, hilar nodes (larger ones halved),
- 2.) 6 sections,
- 3.) - 9.) All material (in 3., 4. + 9. preparation halved in each case),
- 15 blocks, partly Elastica-van Gieson, PAS, diastase-PAS, iron staining.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Large, intermediate to peripheral bronchopulmonary, histologically poorly differentiated, large-cell and polymorphocellular nonkeratinizing squamous cell carcinoma of the right lower lobe of the lung mainly located in S8.

TNM classification according to this picture pT2 pN0 pMX R0, stage IB. 034.3 M8070/3.

Secondary diagnosis/diagnoses:

Focally marked active chronic inflammation predominantly in the tumor and focal chronic organizing retention pneumonia at the tumor margin (sample 1.)). Fibrinous chronic granulating and fibrosing visceral (sample 1.)) and parietal pleuritis (sample 2.)). Uncharacteristic chronic, predominantly interstitial inflammation and fibrosis associated with focal fibrous and small honeycomb-like parenchyma remodeling along the ventrobasal margin of S8. Subpleural accentuated intraalveolar macrophage accumulation in S10 (sample 1.)). Lymph nodes with uncharacteristic reactive lesions and anthracotic pigment deposits (samples 1.) and 3.) - 9.)).

Remark/addendum:

An unequivocal infiltration of the visceral pleura cannot be found. The resection margin of the bronchus and vessels and all lymph nodes identified and excised are tumor-free.

No asbestos bodies are found in the prepared section planes. But very much further-reaching investigations, especially dust analyses, are needed to determine the asbestos exposure of the lung.

Source: NCI Genomic Data Commons file a504f7e7-a2ef-44e2-ba8a-fca022605081 (TCGA-66-2773.406DB03F-3258-48B3-B0DE-B7388D63A559.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).